Somatic mutation profile of tumor specimen C3N-04611-01 (aliquot CPT0261520006) from CPTAC case C3N-04611, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 55.4 years (20,250 days).
Specimen C3N-04611-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7beed5f5-e82c-4b35-9409-ed6cc893feac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04611-71 (Blood Derived Normal), aliquot CPT0261640002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc1669cb-e26c-4982-bcba-35a0283f7d7a

The open-access MAF lists 121 somatic variants for this specimen: 92 protein-altering or splice-affecting, 17 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 17, Intron 7, Frame Shift Del 5, Nonsense Mutation 3, In Frame Del 2, 5'Flank 1, RNA 1, 3'UTR 1, 3'Flank 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP27B1 | c.171del p.L58Cfs*20 | Frame Shift Del (DEL) | VAF 54/374 reads (14%) | catalogued as rs763437121; ClinVar: pathogenic; called by mutect2, varscan2
- FBXW7 | c.1513C>A p.R505S (on ENST00000281708 / NM_001349798.2; = p.R425S on NM_018315.5) | Missense Mutation (SNP) | VAF 68/393 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 60/333 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATIC | c.1102G>A p.D368N | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.989); catalogued as COSV52695157; called by muse, mutect2, varscan2
- BOP1 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 71/524 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1340819628; called by muse, mutect2, varscan2
- CABIN1 | c.2795C>T p.T932M | Missense Mutation (SNP) | VAF 70/483 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs372122646; called by muse, mutect2, varscan2
- CDKN2A | c.243del p.V82Cfs*64 | Frame Shift Del (DEL) | VAF 93/678 reads (14%) | catalogued as CD951647, COSV58688708; called by mutect2, pindel, varscan2
- COL6A3 | c.9344C>T p.P3115L | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs138109666, COSV99801344; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPA | c.199G>T p.V67F | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99615531; called by muse, mutect2
- COPG1 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs376964607; called by muse, mutect2, varscan2
- DDX60 | c.278C>G p.A93G | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as COSV67095074; called by muse, varscan2
- DLGAP4 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 58/374 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as rs746279816, COSV59419693, COSV59419757; called by muse, mutect2, varscan2
- ERCC2 | c.907G>A p.A303T | Missense Mutation (SNP) | VAF 32/262 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.028); catalogued as COSV55544660; called by muse, mutect2, varscan2
- FAM120C | c.2287C>A p.L763M | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60260777; called by muse, mutect2, varscan2
- IFNA14 | c.167G>A p.R56K | Missense Mutation (SNP) | VAF 56/354 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV66516341; called by muse, mutect2, varscan2
- LILRB5 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 44/615 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs369202947; called by muse, mutect2
- LRRK2 | c.6974C>T p.S2325F | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as rs754606066, COSV54155422; called by muse, mutect2, varscan2
- MUC16 | c.22303G>A p.E7435K | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); catalogued as rs768933832; called by muse, mutect2, varscan2
- NACC1 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 34/353 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1169277460; called by muse, mutect2
- NFKBIZ | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 63/443 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs189392097; called by muse, mutect2, varscan2
- NPC1L1 | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 61/347 reads (18%) | SIFT tolerated (0.9); PolyPhen benign (0.014); catalogued as rs756628304, COSV56923389; called by muse, mutect2, varscan2
- NWD2 | c.4241C>T p.S1414L | Missense Mutation (SNP) | VAF 51/293 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58758273; called by muse, mutect2, varscan2
- OCA2 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 24/605 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as rs549983090; called by muse, mutect2
- P3H1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 79/350 reads (23%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.036); catalogued as rs746863189; called by muse, mutect2, varscan2
- PCDH15 | c.1745C>T p.T582M | Missense Mutation (SNP) | VAF 63/310 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752608084, COSV57303490, COSV57332850; called by muse, mutect2, varscan2
- PCDHA1 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 96/637 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.079); catalogued as rs781972006; called by muse, mutect2, varscan2
- PDYN | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 37/280 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs1165705234; called by muse, mutect2, varscan2
- PLEC | c.6994C>G p.L2332V (on ENST00000322810 / NM_201380.4; = p.L2222V on NM_000445.5) | Missense Mutation (SNP) | VAF 30/892 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as rs782292253; called by muse, mutect2
- PPARA | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 66/510 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.035); catalogued as rs937915400; called by muse, mutect2, varscan2
- PRDM15 | c.3289G>A p.E1097K | Missense Mutation (SNP) | VAF 38/584 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.339); catalogued as COSV54156232; called by muse, mutect2
- RICTOR | c.2425C>T p.L809F | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV57117463; called by muse, mutect2, varscan2
- RP1 | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55118474; called by muse, mutect2
- SIRT6 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 45/584 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs201007105, COSV50173533; called by muse, mutect2
- SLC17A1 | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.178); catalogued as rs1051517672, COSV55077951; called by muse, mutect2, varscan2
- SP110 | c.1904G>T p.W635L | Missense Mutation (SNP) | VAF 72/402 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV51247235; called by muse, mutect2, varscan2
- SREBF2 | c.1972G>A p.E658K | Missense Mutation (SNP) | VAF 54/325 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1014982236, COSV99071265; called by muse, mutect2, varscan2
- SYTL2 | c.2092G>A p.E698K (on ENST00000528231 / NM_001162951.2; = p.E674K on NM_032943.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs372798070; called by muse, mutect2, varscan2
- TFAP2D | c.826T>G p.L276V | Missense Mutation (SNP) | VAF 27/266 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99147357, COSV99148083; called by muse, mutect2
- TTC13 | c.1166A>G p.Y389C | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs749969310, COSV64170386; called by muse, mutect2, varscan2
- ZKSCAN5 | c.2072del p.N691Mfs*12 | Frame Shift Del (DEL) | VAF 47/375 reads (13%) | catalogued as rs556762260; called by mutect2, pindel, varscan2
- ZNF292 | c.7535A>G p.N2512S | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368478191; called by muse, mutect2
- ZNF549 | c.1342A>G p.I448V (on ENST00000376233 / NM_001199295.2; = p.I435V on NM_153263.2) | Missense Mutation (SNP) | VAF 48/302 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs750472577; called by muse, mutect2, varscan2
- ZNF679 | c.1028A>C p.K343T | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV55382120; called by muse, mutect2
- ADIPOR1 | c.110A>G p.K37R | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANK1 | c.1442G>A p.G481D | Missense Mutation (SNP) | VAF 118/753 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by mutect2, varscan2
- ANKRD9 | c.842G>A p.R281H | Missense Mutation (SNP) | VAF 86/379 reads (23%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- ARFGEF2 | c.4027T>C p.C1343R | Missense Mutation (SNP) | VAF 98/643 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCHCR1 | c.956C>T p.S319L | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CD22 | c.798G>T p.E266D | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.167); called by muse, mutect2
- CHD7 | c.6700G>A p.E2234K | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.587); called by muse, mutect2
- COL4A5 | c.287G>C p.G96A | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- COP1 | c.417C>A p.C139* | Nonsense Mutation (SNP) | VAF 9/112 reads (8%) | called by muse, mutect2
- DENND5A | c.257_265del p.E86_P89delinsA | In Frame Del (DEL) | VAF 26/213 reads (12%) | called by mutect2, pindel, varscan2
- FOLH1 | c.1165C>A p.Q389K | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- GRM6 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 37/278 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- GTSE1 | c.226C>T p.P76S | Missense Mutation (SNP) | VAF 48/410 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- HEATR1 | c.2500G>A p.E834K | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.11); called by muse, mutect2
- HELZ2 | c.1688G>T p.R563L | Missense Mutation (SNP) | VAF 100/705 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- KIAA0586 | c.3268A>G p.M1090V (on ENST00000619416 / NM_001244190.2; = p.M1029V on NM_014749.5) | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLK6 | c.442G>C p.D148H | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, varscan2
- KMT2D | c.3955del p.H1319Mfs*11 | Frame Shift Del (DEL) | VAF 19/141 reads (13%) | called by mutect2, pindel, varscan2
- LBR | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 11/191 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.091); called by muse, mutect2
- MATR3 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- MTMR9 | c.919C>G p.H307D | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- MTR | c.1536A>C p.K512N | Missense Mutation (SNP) | VAF 35/273 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC16 | c.18725A>G p.E6242G | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYCBP2 | c.10807A>T p.I3603F (on ENST00000357337; = p.I3641F on NM_015057.5) | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- NRXN2 | c.2365C>A p.Q789K | Missense Mutation (SNP) | VAF 38/378 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- NSD1 | c.1850C>G p.S617* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- NUDCD1 | c.148C>G p.Q50E | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- OR6P1 | c.746T>G p.V249G | Missense Mutation (SNP) | VAF 34/620 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.491); called by muse, mutect2
- PCDHGA11 | c.379A>G p.I127V | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- PHLDB2 | c.3260A>T p.Q1087L (on ENST00000393925 / NM_001134439.2; = p.Q1044L on NM_145753.2) | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.097); called by muse, mutect2
- PLSCR4 | c.313C>G p.P105A | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.282); called by muse, mutect2
- POLR3A | c.968G>A p.S323N | Missense Mutation (SNP) | VAF 64/415 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- POSTN | c.952G>T p.G318* | Nonsense Mutation (SNP) | VAF 19/232 reads (8%) | called by muse, mutect2
- PPP4C | c.99-1G>C p.X33_splice | Splice Site (SNP) | VAF 28/260 reads (11%) | called by muse, mutect2
- PRPSAP2 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- PSMD7 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- RB1 | c.2040C>G p.I680M | Missense Mutation (SNP) | VAF 15/388 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.687); called by muse, mutect2
- SAMD9 | c.3518G>A p.R1173K | Missense Mutation (SNP) | VAF 23/734 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SHISA7 | c.193_210del p.P65_G70del | In Frame Del (DEL) | VAF 18/172 reads (10%) | called by mutect2, pindel
- SIGLEC15 | c.247G>C p.A83P | Missense Mutation (SNP) | VAF 85/575 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- SLAIN2 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.951); called by muse, varscan2
- SLC7A10 | c.1177T>C p.F393L | Missense Mutation (SNP) | VAF 39/553 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.364); called by muse, mutect2
- SYTL5 | c.191G>C p.C64S | Missense Mutation (SNP) | VAF 58/209 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM249 | c.118A>G p.S40G | Missense Mutation (SNP) | VAF 43/302 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.888); called by mutect2, varscan2
- TMPRSS7 | c.1409_1419del p.P470Rfs*17 (on ENST00000452346; = p.P344Rfs*17 on NM_001042575.2) | Frame Shift Del (DEL) | VAF 62/226 reads (27%) | called by mutect2, pindel, varscan2
- TRIP11 | c.3003C>G p.S1001R | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.195); called by muse, mutect2
- TTC25 | c.1964G>A p.G655E | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); called by muse, mutect2
- WWP2 | c.1166G>T p.R389I | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZBTB39 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 44/199 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AMZ1 | c.1224A>G p.E408= | Silent (SNP) | VAF 15/374 reads (4%) | catalogued as rs1260696917; called by muse, mutect2
- ATP10A | c.792G>A p.L264= | Silent (SNP) | VAF 49/392 reads (13%) | catalogued as COSV100791246, COSV100791386; called by muse, mutect2, varscan2
- ELFN1 | c.726C>T p.I242= | Silent (SNP) | VAF 52/264 reads (20%) | called by muse, mutect2, varscan2
- ELFN2 | c.2064C>T p.S688= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as rs759784030; called by muse, mutect2, varscan2
- ELOVL2 | c.744C>G p.L248= | Silent (SNP) | VAF 16/145 reads (11%) | called by muse, varscan2
- FUT4 | c.1200C>T p.L400= | Silent (SNP) | VAF 39/193 reads (20%) | called by muse, mutect2, varscan2
- GRK6 | c.250C>T p.L84= | Silent (SNP) | VAF 25/129 reads (19%) | called by muse, mutect2, varscan2
- ITGBL1 | c.34C>T p.L12= | Silent (SNP) | VAF 20/215 reads (9%) | called by muse, mutect2, varscan2
- NMT2 | c.933G>C p.V311= | Silent (SNP) | VAF 44/221 reads (20%) | called by muse, mutect2, varscan2
- OR2B3 | c.912G>T p.L304= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV65850944; called by muse, mutect2, varscan2
- OXSR1 | c.855A>G p.L285= | Silent (SNP) | VAF 18/171 reads (11%) | catalogued as rs1470925249; called by muse, mutect2, varscan2
- PCDH8 | c.882C>G p.R294= | Silent (SNP) | VAF 21/199 reads (11%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.2325C>T p.Y775= | Silent (SNP) | VAF 64/396 reads (16%) | catalogued as rs761615702, COSV53901345; called by muse, mutect2, varscan2
- SULF1 | c.1572C>T p.F524= | Silent (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- SV2B | c.1662C>A p.I554= | Silent (SNP) | VAF 20/341 reads (6%) | called by muse, mutect2
- TMEM223 | c.84G>A p.T28= | Silent (SNP) | VAF 71/382 reads (19%) | catalogued as COSV99584848; called by muse, mutect2, varscan2
- ZNF333 | c.327G>A p.R109= | Silent (SNP) | VAF 41/226 reads (18%) | called by muse, mutect2, varscan2
- C14orf39 | chr14:60433387 C>A | 3'Flank (SNP) | VAF 22/165 reads (13%) | called by muse, mutect2, varscan2
- CMPK2 | chr2:6865895 C>A | 5'Flank (SNP) | VAF 39/259 reads (15%) | called by muse, mutect2, varscan2
- CRACR2B | c.278-179C>T | Intron (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2
- DDX3X | c.104-11T>A | Intron (SNP) | VAF 16/48 reads (33%) | catalogued as rs980049998, COSV67864083; called by muse, mutect2, varscan2
- EFEMP2 | c.*353C>G | 3'UTR (SNP) | VAF 85/552 reads (15%) | called by muse, mutect2, varscan2
- EPHA4 | c.2075-11G>A | Intron (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- FRMD7 | c.-4G>C | 5'UTR (SNP) | VAF 43/158 reads (27%) | called by muse, mutect2, varscan2
- LINC02740 | n.286G>A | RNA (SNP) | VAF 30/273 reads (11%) | catalogued as rs965426550; called by muse, mutect2, varscan2
- PDXDC1 | c.242+20C>T | Intron (SNP) | VAF 30/383 reads (8%) | called by muse, mutect2
- RIMS2 | c.3821+899G>T | Intron (SNP) | VAF 13/115 reads (11%) | called by muse, mutect2, varscan2
- TTC39C | c.985-895A>G | Intron (SNP) | VAF 29/191 reads (15%) | called by muse, mutect2, varscan2
- VPS50 | c.298-12A>G | Intron (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
